Somatic mutation profile of tumor specimen TCGA-A6-6649-01A (aliquot TCGA-A6-6649-01A-11D-1771-10) from TCGA case TCGA-A6-6649, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 66.4 years (24,237 days).
Specimen TCGA-A6-6649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 615922d3-d3ae-4a5b-badd-2ecd82a046d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6649-10A (Blood Derived Normal), aliquot TCGA-A6-6649-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2453b46a-c813-4dd4-ae03-690127666432

The open-access MAF lists 119 somatic variants for this specimen: 89 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 27, Nonsense Mutation 6, 3'UTR 1, Splice Region 1, Intron 1, Frame Shift Ins 1, In Frame Del 1, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.821T>A p.V274D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs369701134; called by muse, mutect2, varscan2
- ACAN | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771241836, COSV61361708; called by muse, mutect2
- ADAMTSL3 | c.1202G>T p.C401F | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54450680; called by muse, mutect2, varscan2
- ADCY2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100602107; called by muse, varscan2
- AMDHD2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1374722747, COSV53550913; called by muse, mutect2, varscan2
- ANKRD35 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV62910513; called by muse, mutect2, varscan2
- ARHGEF17 | c.2896T>C p.F966L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV55233118; called by muse, mutect2, varscan2
- ATXN7 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1364765767, COSV99893962; called by muse, mutect2
- BRAT1 | c.2169_2171del p.L724del | In Frame Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs762488461; called by mutect2, pindel, varscan2
- CACNA1H | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186328765, COSV61991376; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CCM2 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as rs139533504; called by muse, mutect2, varscan2
- CCT6A | c.1268T>A p.I423N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV51905881; called by muse, mutect2, varscan2
- CD163 | c.3382C>A p.L1128I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); catalogued as COSV63133076; called by muse, mutect2
- CD163L1 | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV58017322; called by muse, mutect2
- CD163L1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV58017332; called by muse, mutect2, varscan2
- CLEC4G | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1294612150, COSV61003413; called by muse, mutect2, varscan2
- CLUH | c.2197C>T p.Q733* (on ENST00000435359; = p.Q772* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV70928859; called by muse, mutect2, varscan2
- CNGA2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs769231187, COSV61704551; called by muse, mutect2, varscan2
- CNGB1 | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781615372, COSV51901505; called by muse, mutect2, varscan2
- CRYBG3 | c.8777G>A p.G2926E | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1389251201, COSV99476721; called by muse, mutect2, varscan2
- CYYR1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54827898; called by muse, mutect2, varscan2
- DCUN1D3 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60953481; called by muse, mutect2, varscan2
- DDR2 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63370105; called by muse, mutect2, varscan2
- DMBT1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1239402169, COSV57545827; called by muse, mutect2, varscan2
- DNAJC28 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58721682; called by muse, mutect2, varscan2
- DOP1B | c.6646-1G>T p.X2216_splice | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV67690778; called by mutect2, varscan2
- DPH6 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 46/166 reads (28%) | catalogued as rs371901885; called by muse, mutect2, varscan2
- DPYD | c.3023C>A p.T1008K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV64599276; called by muse, mutect2
- DYM | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53985032; called by muse, mutect2, varscan2
- ECSIT | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV52939605; called by muse, mutect2, varscan2
- ENTPD4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62269192; called by muse, mutect2, varscan2
- FBN2 | c.1589A>T p.N530I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV52517272; called by muse, mutect2, varscan2
- FCSK | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as rs1357592599, COSV55371485; called by muse, mutect2, varscan2
- FLG | c.4930G>C p.G1644R | Missense Mutation (SNP) | VAF 62/663 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV64240894, COSV64250888; called by muse, mutect2
- FSHR | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV58617482, COSV58624672; called by muse, mutect2, varscan2
- FUT5 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs752890602, COSV53136668; called by muse, mutect2, varscan2
- GLIS3 | c.1450A>G p.T484A | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1432910857, COSV60929822; called by muse, mutect2, varscan2
- GPR42 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV101497374; called by muse, mutect2
- GPX6 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188213920, COSV62656952; called by muse, mutect2, varscan2
- IGSF10 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV56786128; called by muse, mutect2
- KLF8 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1555939511, COSV63847819; called by muse, mutect2, varscan2
- KRTAP6-2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 25/292 reads (9%) | PolyPhen probably damaging (0.987); catalogued as rs533416500, COSV58182373; called by muse, mutect2
- LDB3 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.702); catalogued as COSV53942439; called by muse, varscan2
- LPA | c.6002A>T p.K2001I | Missense Mutation (SNP) | VAF 44/489 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV60299005; called by muse, mutect2
- LRP1B | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 56/171 reads (33%) | catalogued as COSV101256443, COSV67254380; called by muse, mutect2, varscan2
- LRRC7 | c.2341C>T p.R781W (on ENST00000651989 / NM_001370785.2; = p.R748W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs745328044, COSV50469795; called by muse, mutect2, varscan2
- LYPD2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs766307085, COSV63649396, COSV63649517; called by muse, mutect2, varscan2
- MAPKAPK5 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as rs745405567, COSV72431626; called by muse, mutect2, varscan2
- MSGN1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs912920270, COSV99808694; called by muse, mutect2
- MUC17 | c.9596C>G p.T3199S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV60290449; called by muse, mutect2, varscan2
- MUC17 | c.12245C>T p.T4082M | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs552714025, COSV60290457; called by muse, mutect2, varscan2
- NAV2 | c.1336C>T p.R446W (on ENST00000396087 / NM_001244963.2; = p.R423W on NM_145117.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs775021883, COSV62324310; called by muse, mutect2, varscan2
- NCAN | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1396995508, COSV53046925; called by muse, mutect2, varscan2
- NEPRO | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs372396645; called by muse, mutect2, varscan2
- NLGN2 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1479955408, COSV100080762; called by muse, mutect2, varscan2
- OSBPL6 | c.2398G>T p.G800* | Nonsense Mutation (SNP) | VAF 15/224 reads (7%) | catalogued as COSV51934426; called by muse, mutect2
- PLAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs773140572, COSV99535039; called by muse, mutect2, varscan2
- PLPPR1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs768378346, COSV66453691; called by muse, mutect2, varscan2
- PNISR | c.2393A>T p.H798L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65079607; called by muse, mutect2
- PTGFR | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100882249; called by muse, mutect2
- PTPRM | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100155762; called by muse, mutect2
- RIMS3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs374489459; called by muse, mutect2, varscan2
- RIN1 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100254419; called by muse, mutect2, varscan2
- RNF43 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV68458431; called by muse, mutect2, varscan2
- RPE65 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV52016441; called by muse, mutect2, varscan2
- SALL2 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs375899234; called by muse, mutect2, varscan2
- SDK1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.117); catalogued as rs750500679, COSV67371383; called by muse, mutect2, varscan2
- SLITRK1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV65674876; called by muse, mutect2, varscan2
- SORCS1 | c.2584G>A p.V862M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs759089178, COSV53870768; called by muse, mutect2, varscan2
- SORCS2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs759118679, COSV61171167; called by muse, mutect2, varscan2
- SRRM2 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs745594673, COSV100070433; called by mutect2, varscan2
- SV2B | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as rs776050433, COSV100370469, COSV57700676, COSV57701598; called by muse, mutect2, varscan2
- SYNE1 | c.24604C>T p.R8202C (on ENST00000367255 / NM_182961.4; = p.R8131C on NM_033071.3) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280986749, COSV99549489; called by muse, mutect2, varscan2
- SYNJ2 | c.2749C>T p.Q917* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs752714124, COSV100840074; called by muse, mutect2
- TDO2 | c.306C>G p.V102= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as COSV72232821; called by muse, mutect2, varscan2
- TFAP2B | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV53828151; called by muse, mutect2, varscan2
- TTN | c.31324G>A p.E10442K (on ENST00000591111; = p.E9515K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/200 reads (7%) | PolyPhen benign (0.031); catalogued as COSV100600075; called by muse, mutect2
- UCMA | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs377345564; called by muse, mutect2, varscan2
- VPS8 | c.4019C>T p.S1340L (on ENST00000625842 / NM_001349294.1; = p.S1338L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54987122; called by muse, mutect2, varscan2
- YTHDF3 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101572364; called by muse, mutect2, varscan2
- ZFHX4 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.523); catalogued as rs568208828, COSV50888940; called by muse, mutect2, varscan2
- ZNF517 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs866431601, COSV63464852; called by muse, mutect2, varscan2
- ZNF536 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs556954524, COSV62824617, COSV62826657; called by muse, mutect2, varscan2
- ZNF98 | c.1499A>C p.N500T | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV63336896; called by muse, mutect2
- GABRB2 | c.673dup p.S225Ffs*13 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- SERPINB10 | c.269_270del p.S90* | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by pindel, varscan2
- ARHGAP10 | c.843G>A p.P281= | Silent (SNP) | VAF 39/259 reads (15%) | catalogued as rs546870590, COSV60600172; called by muse, mutect2, varscan2
- CHRM2 | c.951T>C p.D317= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs77845403, COSV57766634; ClinVar: likely benign; called by muse, mutect2, varscan2
- DEFB124 | c.153G>A p.A51= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs143418400, COSV58343127; called by muse, mutect2, varscan2
- DOCK8 | c.2220G>A p.E740= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV66620553; called by muse, mutect2
- EMID1 | c.1323G>A p.E441= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV53323598; called by muse, mutect2, varscan2
- FAF2 | c.228C>T p.H76= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56131288; called by muse, mutect2, varscan2
- GRAMD1B | c.1977C>T p.L659= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV59205348; called by muse, mutect2
- GRB10 | c.750A>C p.A250= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV60011096; called by muse, mutect2, varscan2
- GRM6 | c.1317G>A p.R439= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs528238305, COSV51443052; called by mutect2, varscan2
- HIPK1 | c.117C>T p.N39= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1445889651, COSV65784853; called by muse, mutect2, varscan2
- HTR5A | c.450G>A p.T150= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55283807; called by muse, mutect2, varscan2
- ITGB7 | c.714C>T p.D238= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as rs1415198191, COSV57238891; called by muse, mutect2, varscan2
- KCNJ8 | c.1195C>A p.R399= | Silent (SNP) | VAF 51/285 reads (18%) | catalogued as COSV53715850; called by muse, mutect2, varscan2
- LUZP1 | c.189G>A p.A63= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as rs184592362, COSV56501629; called by muse, mutect2, varscan2
- NTRK1 | c.876G>A p.T292= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs749993335, COSV100693832, COSV62325974; called by muse, mutect2, varscan2
- OBP2B | c.294C>T p.L98= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV64402540; called by muse, mutect2, varscan2
- PCDHA1 | c.1884G>A p.T628= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV65373643; called by muse, mutect2, varscan2
- PCNX1 | c.6363C>G p.A2121= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99454689; called by muse, mutect2, varscan2
- SLC66A1 | c.180C>T p.A60= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV64320975; called by muse, mutect2, varscan2
- SLIT2 | c.213G>A p.T71= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as rs377588103, COSV99879745; called by muse, mutect2, varscan2
- TFPI | c.174G>A p.A58= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs780564015, COSV51900596; called by muse, mutect2, varscan2
- TMEM200C | c.123G>A p.V41= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV101274797; called by muse, mutect2
- TTN | c.39507C>A p.V13169= (on ENST00000591111; = p.V5745= on NM_003319.4) | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV60103830; called by muse, mutect2, varscan2
- TTN | c.2649C>T p.F883= (on ENST00000591111; = p.F837= on NM_003319.4) | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as rs775588479, COSV59887660; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UNK | c.1083G>A p.P361= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs372005181, COSV53147017; called by muse, mutect2, varscan2
- VWA7 | c.1449A>G p.K483= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100991771; called by mutect2, varscan2
- ZFP42 | c.720T>C p.T240= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1284860295, COSV100478701; called by muse, mutect2
- ATP2B2 | c.*148G>A | 3'UTR (SNP) | VAF 80/203 reads (39%) | catalogued as rs1215036750, COSV100660576, COSV59497773; called by muse, mutect2, varscan2
- GASK1B | c.910+188T>G | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99647404; called by muse, mutect2, varscan2
- SSPOP | n.1144G>A | RNA (SNP) | VAF 32/152 reads (21%) | catalogued as rs760253070, COSV50487735; called by muse, mutect2, varscan2
